TCGA case TCGA-5P-A9JW — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University Hospital Erlangen. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/07d409a0-d0dd-415a-95c3-38c26a518c56

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 64 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 64.5 years (23,570 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,241 days (8.9 years).
   Pathology details: Consistent pathology review: Yes; Prcc type: Type 2.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 73.4 years (26,798 days); Days to diagnosis: 3,228 days (8.8 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 3,228 (post initial treatment): Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 3,241.

Molecular and laboratory tests
- Hemoglobin: Normal.
- Erythrocyte Sedimentation Rate: Normal.
- Platelets: Normal.
- Calcium: Normal.
- Leukocytes: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 97 kg; Height: 186 cm; BMI: 28.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-5P-A9JW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 24 mg.
  Slide TCGA-5P-A9JW-01A-01-TS1: Section location: Top; Percent tumor cells: 81; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 19; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 0.
- Sample TCGA-5P-A9JW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-5P-A9JW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,241 days; disease-specific survival: no event (censored), 3,241 days; disease-free interval: event (new tumor event after initially disease-free), 3,228 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 3,228 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-5P-A9JW-01A-11D-A42I-01): tumor purity 0.64, ploidy 2, whole-genome doublings 0.
